Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6496, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6496-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. RIGHT PELVIC LYMPH NODES
- B. LEFT PELVIC LYMPH NODES
- C. PROSTATE

TCGA - G9 - 6496

SPECIMEN(S):

- A. RIGHT PELVIC LYMPH NODES
- B. LEFT PELVIC LYMPH NODES
- C. PROSTATE

GROSS DESCRIPTION:

A. RIGHT PELVIC LYMPH NODES

Received in formalin are multiple tan-pink fragments of fibrofatty tissue aggregating to 4.0 x 3.0 x 1.0 cm. Dissection reveals one tan-pink lymph node measuring 3.8 x 1.5 x 1.5 cm. The specimen is serially sectioned and submitted entirely in cassettes A1-A3.

B. LEFT PELVIC LYMPH NODES

Received in formalin are multiple tan-pink fragments of fibrofatty tissue aggregating to 2.0 x 1.8 x 1.0 cm. Dissection reveals 3 possible lymph nodes ranging from 0.7 x 0.5 x 0.5 cm to 1.5 x 1.0 x 1.0 cm.

Section code:

- B1: 2 possible lymph nodes
- B2-B3: 1 lymph node serially sectioned

C. PROSTATE

Received fresh is a 39 gm resected prostate, 5.0 cm from left to right, 3.6 cm from apex to base, 3.5 cm from anterior to posterior, with attached segments of right and left seminal vesicle and vas deferens. The capsule is tan-pink, smooth and intact. The specimen is inked as follows: apex-red, anterior-orange, right lateral-green, left lateral-yellow, base-blue, posterior-black. After removal of the apex and base the remaining prostate weight is 23 gm. The specimen is serially sectioned from apex to base at 4-5 mm intervals to reveal beige-tan spongy tissue. No nodules can be grossly identified. A portion of the specimen is submitted for tissue procurement level 2 and a shave of level 3. The remainder of the specimen is submitted as follows:

- C1: level 1 right anterior
- C2: level 1 right posterior
- C3: level 1 left anterior
- C4: level 1 left posterior
- C5: level 2 capsule right anterior
- C6: level 2 right posterior capsule
- C7: level 2 left anterior capsule
- C8: level 2 left anterior capsule
- C9: level 4 right anterior
- C10: level 4 right posterior
- C11: level 4 left anterior
- C12: level 4 left posterior
- C13: right apex perpendicular sections taken
- C14: left apex perpendicular sections taken
- C15: right base with periurethral margin
- C16: left base with periurethral margin
- C17: right lateral base
- C18: left lateral base
- C19: right base
- C20: left base
- C21: representative section of right seminal vesicle
- C22: representative section of right vas deferens
- C23: representative section of left seminal vesicle
- C24: representative section of left vas deferens

DIAGNOSIS:

- A. LYMPH NODES, RIGHT PELVIC, EXCISION:
- TWELVE LYMPH NODES WITH NO EVIDENCE OF ADENOCARCINOMA (0/12)
- B. LYMPH NODES, LEFT PELVIC, EXCISION:
- THREE LYMPH NODES WITH NO EVIDENCE OF ADENOCARCINOMA (0/3)

[page 2 of 2]
C. PROSTATE, PROSTATECTOMY:

- PROSTATIC ADENOCARCINOMA, GLEASON GRADE 4+3 (TOTAL SCORE = 7), INVOLVING THE RIGHT AND LEFT LOBES OF PROSTATE AND GLAND CONFINED (SEE SYNOPSIS REPORT).
SYNOPSIS REPORT - PROSTATE GLAND

Specimens Involved

Specimens: C: PROSTATE

Location: Left

Right

Posterior lateral

Apical

Anterior

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 20%

Gleason Grade/Sum:: Grade 4 + 3 , Sum 7

High Grade PIN Present: No

Perineural Invasion: Yes

Vascular/Lymphatic Invasion: No

Seminal Vesicle Invasion: No

Periprostatic Fat Involved: No

Bladder Neck Involved: No

Margins Involvement: No

Frozen Performed: No

Lymph Nodes: Negative Right 0 / 12 Left 0 / 3

Other Pathologic Findings: None identified

Pathological Staging (pTNM): T 2c N 0 M X

CLINICAL HISTORY:

Not given

PRE-OPERATIVE DIAGNOSIS:

Prostate ca

Source: NCI Genomic Data Commons file 43d7b6f7-e648-42c3-a145-9995f3066c06 (TCGA-G9-6496.193CCA51-2D1F-49AA-AFDB-63A55D689C86.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).